Somatic mutation profile of tumor specimen TCGA-AG-3581-01A (aliquot TCGA-AG-3581-01A-01D-1989-10) from TCGA case TCGA-AG-3581, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage I; Age at diagnosis: 63.9 years (23,345 days).
Specimen TCGA-AG-3581-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 60a2ef22-9257-4dc9-b1c4-c76d642eb09f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3581-10A (Blood Derived Normal), aliquot TCGA-AG-3581-10A-01D-1989-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ebd2567d-3eb4-46ca-9c9a-bcd2a4d10ec9

The open-access MAF lists 19 somatic variants for this specimen: 13 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, Nonsense Mutation 3, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A2ML1 | c.1870C>G p.P624A | Missense Mutation (SNP) | VAF 127/438 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as COSV100228795; called by muse, mutect2, varscan2
- ABCA2 | c.5716G>A p.V1906I (on ENST00000614293; = p.V1876I on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.733); catalogued as rs775000577, COSV55800167; called by muse, mutect2, varscan2
- ASL | c.1222C>G p.L408V | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.323); catalogued as COSV100508865, COSV100508934; called by muse, mutect2, varscan2
- BSN | c.10777G>T p.D3593Y | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99608031; called by muse, mutect2, varscan2
- CHRD | c.1209C>A p.C403* | Nonsense Mutation (SNP) | VAF 10/21 reads (48%) | catalogued as COSV99200350; called by muse, mutect2, varscan2
- DSPP | c.1234G>C p.G412R | Missense Mutation (SNP) | VAF 76/243 reads (31%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.05); catalogued as COSV56808593, COSV99217090; called by muse, mutect2, varscan2
- KCNA5 | c.1241C>A p.S414Y | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99363823; called by muse, varscan2
- KDM2B | c.2150G>A p.W717* | Nonsense Mutation (SNP) | VAF 72/237 reads (30%) | catalogued as COSV100997363, COSV100997672; called by muse, mutect2, varscan2
- KNDC1 | c.1076C>A p.P359H | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV100464346; called by muse, mutect2, varscan2
- SEMA7A | c.575G>A p.R192Q | Missense Mutation (SNP) | VAF 55/184 reads (30%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.571); catalogued as rs778351405, COSV56090109; called by muse, mutect2, varscan2
- STEAP4 | c.952C>T p.R318* | Nonsense Mutation (SNP) | VAF 54/200 reads (27%) | catalogued as rs370212764, COSV57329885; called by muse, mutect2, varscan2
- TRAF7 | c.1046A>T p.E349V | Missense Mutation (SNP) | VAF 47/156 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.092); catalogued as COSV100399386; called by muse, mutect2, varscan2
- ROBO2 | c.3244del p.L1082Ffs*91 | Frame Shift Del (DEL) | VAF 71/307 reads (23%) | called by mutect2, pindel, varscan2
- ABCC5 | c.2697C>T p.T899= | Silent (SNP) | VAF 89/298 reads (30%) | catalogued as COSV99656714; called by muse, mutect2, varscan2
- NAV3 | c.1200G>A p.P400= | Silent (SNP) | VAF 41/131 reads (31%) | catalogued as rs202050601, COSV57077489, COSV99894680; called by muse, mutect2, varscan2
- PLXNA3 | c.5472G>T p.L1824= | Silent (SNP) | VAF 39/59 reads (66%) | catalogued as COSV100859906; called by muse, mutect2, varscan2
- RTTN | c.1767G>A p.P589= | Silent (SNP) | VAF 122/242 reads (50%) | catalogued as rs758337001, COSV99731928; called by muse, mutect2, varscan2
- SLC38A8 | c.432G>A p.P144= | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as rs758588764, COSV100230422; called by muse, mutect2, varscan2
- OR2U1P | n.311C>T | RNA (SNP) | VAF 68/200 reads (34%) | catalogued as rs369399120; called by muse, mutect2, varscan2
